CCDI case PBBKTJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cb108658-19aa-448d-a211-f5ed9cd12aba

Demographics
Sex at birth: male; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Pleomorphic xanthoastrocytoma: ICD-O-3 morphology code: 9424/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.7 years (3,190 days).

Biospecimens (3 samples)
- Sample 0DB97M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DB97V: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DB980: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
